Somatic mutation profile of tumor specimen TCGA-12-1089-01A (aliquot TCGA-12-1089-01A-01W-0611-08) from TCGA case TCGA-12-1089, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.1 years (23,419 days).
Specimen TCGA-12-1089-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73059fef-6a01-4914-9ab4-20779723eaf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1089-10C (Blood Derived Normal), aliquot TCGA-12-1089-10C-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5aaa6f2e-d192-4b5d-afb4-e60bfa0c64e8

The open-access MAF lists 75 somatic variants for this specimen: 56 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Nonsense Mutation 6, Frame Shift Del 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3582C>G p.F1194L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52211220, COSV52211906, COSV99286943; called by muse, varscan2
- ALS2 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 20/444 reads (5%) | catalogued as COSV51886914, COSV99970074; called by muse, mutect2
- ATP8B1 | c.3463G>T p.V1155L | Missense Mutation (SNP) | VAF 64/716 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99377893; called by muse, mutect2
- AURKC | c.371C>T p.P124L (on ENST00000302804 / NM_001015878.2; = p.P90L on NM_003160.3) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV100248995; called by muse, mutect2, varscan2
- CARTPT | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 118/3836 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.675); catalogued as rs77043527, COSV99704007; called by muse, mutect2
- CCDC158 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs369057239, COSV66357379; called by muse, mutect2, varscan2
- CCDC93 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100099517; called by muse, mutect2, varscan2
- CDC5L | c.2185A>G p.M729V | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs776260156, COSV101015208; called by muse, mutect2, varscan2
- CHD7 | c.7925C>T p.T2642I | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101418458; called by muse, mutect2, varscan2
- CNNM4 | c.2181C>A p.N727K | Missense Mutation (SNP) | VAF 42/852 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV100998838; called by muse, mutect2
- CRYBG1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 265/381 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765446944, COSV100954381; called by muse, mutect2, varscan2
- DNAAF5 | c.2318G>A p.C773Y | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99860318; called by muse, mutect2, varscan2
- DNAH3 | c.6398G>A p.G2133E | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049726920, COSV54551022; called by muse, mutect2
- DSG4 | c.2699T>C p.V900A | Missense Mutation (SNP) | VAF 471/1611 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100356427; called by muse, mutect2, varscan2
- EPHA1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs778110783, COSV51970988; called by muse, mutect2, varscan2
- EPHX4 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 9/257 reads (4%) | catalogued as COSV64889310; called by muse, mutect2
- EVC2 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV60389546; called by mutect2, varscan2
- FAM120B | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 99/741 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99380023; called by muse, mutect2, varscan2
- FGF23 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.19); catalogued as COSV52975016; called by muse, mutect2, varscan2
- FSTL3 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV99383951; called by muse, mutect2, varscan2
- GADL1 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 36/272 reads (13%) | catalogued as COSV99245094; called by muse, mutect2, varscan2
- GDF9 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs142443414, COSV99737553; called by muse, mutect2
- GLI1 | c.2985G>T p.L995F | Missense Mutation (SNP) | VAF 34/1177 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99954729; called by muse, mutect2
- GORASP2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as rs767472684, COSV99304751; called by muse, mutect2, varscan2
- GRIA1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as rs770604772, COSV99600965, COSV99602428; called by muse, mutect2, varscan2
- IGSF21 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs779239010, COSV52125632; called by muse, varscan2
- KIF5A | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673594; called by muse, mutect2
- KRTAP9-4 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100484968; called by muse, mutect2, varscan2
- LRBA | c.5126G>C p.G1709A | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.03); catalogued as COSV100842094; called by muse, mutect2
- LTN1 | c.4555C>A p.L1519I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100798229; called by muse, mutect2
- MAGEC1 | c.1178del p.P393Lfs*20 | Frame Shift Del (DEL) | VAF 35/78 reads (45%) | catalogued as COSV53567216; called by mutect2, pindel, varscan2
- MRPL54 | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100349778; called by muse, mutect2, varscan2
- MYH13 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 1106/1415 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs750870108, COSV52839911; called by muse, mutect2, varscan2
- NAV2 | c.2653G>A p.G885S (on ENST00000396087 / NM_001244963.2; = p.G862S on NM_145117.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100587077; called by muse, mutect2
- NUTM1 | c.1895G>T p.S632I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100149215; called by muse, mutect2
- OCLN | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 77/646 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.288); catalogued as COSV100783876; called by muse, mutect2, varscan2
- OR14C36 | c.136G>C p.V46L | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.565); catalogued as COSV100507658, COSV58602490; called by muse, mutect2, varscan2
- OR51A2 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66748180; called by muse, mutect2, varscan2
- OR52N5 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139255166; called by muse, mutect2, varscan2
- PPP1R12B | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 193/265 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV100408497; called by muse, mutect2, varscan2
- PREX2 | c.990A>G p.I330M | Missense Mutation (SNP) | VAF 79/639 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99910004; called by muse, mutect2, varscan2
- PRTG | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101221493; called by muse, mutect2, varscan2
- PTEN | c.787A>T p.K263* | Nonsense Mutation (SNP) | VAF 67/114 reads (59%) | catalogued as rs1554825254, COSV64298269; called by muse, mutect2, varscan2
- PUS3 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs376386339; called by muse, mutect2, varscan2
- PWWP3A | c.362G>T p.R121L (on ENST00000627377; = p.R120L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/733 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.645); catalogued as COSV100262285, COSV60902819; called by muse, mutect2, varscan2
- SLC12A6 | c.1636G>T p.V546F (on ENST00000354181 / NM_001365088.1; = p.V495F on NM_005135.2) | Missense Mutation (SNP) | VAF 30/696 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV99273447; called by muse, mutect2
- SON | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as COSV99279889; called by muse, mutect2
- STARD8 | c.2974T>A p.Y992N | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99367668; called by muse, mutect2, varscan2
- TICRR | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV99180075; called by muse, mutect2, varscan2
- UBR5 | c.4924G>A p.V1642I | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1217790092, COSV99642422; called by muse, mutect2, varscan2
- ZMYND15 | c.1137C>A p.Y379* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV99351824; called by muse, mutect2, varscan2
- ZNF676 | c.544T>C p.F182L (on ENST00000650058; = p.F150L on NM_001001411.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs770981051, COSV101236350; called by muse, mutect2, varscan2
- ZSWIM5 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100655813; called by muse, mutect2, varscan2
- ACTL7A | c.786C>G p.N262K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- KCTD3 | c.2249_2253del p.K750Rfs*3 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by pindel, varscan2
- PIWIL1 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by mutect2, varscan2
- ATP6V0D2 | c.795G>A p.K265= | Silent (SNP) | VAF 108/513 reads (21%) | catalogued as COSV99572072; called by muse, mutect2, varscan2
- BACH2 | c.1179A>G p.G393= | Silent (SNP) | VAF 16/208 reads (8%) | called by mutect2, varscan2
- CNTNAP1 | c.399G>T p.V133= | Silent (SNP) | VAF 21/302 reads (7%) | catalogued as COSV99227031; called by muse, mutect2
- DCAF4L1 | c.120C>A p.T40= | Silent (SNP) | VAF 26/436 reads (6%) | catalogued as rs1202605557, COSV100296007; called by muse, mutect2
- DDX11 | c.120G>C p.G40= | Silent (SNP) | VAF 12/464 reads (3%) | catalogued as COSV99300086; called by muse, mutect2
- ELF4 | c.1254C>T p.T418= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as COSV100257603; called by muse, mutect2, varscan2
- FREM2 | c.2103G>A p.P701= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs117758105, COSV99750967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRD | c.294C>T p.S98= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs1234480091, COSV101059577; called by muse, mutect2
- ITGA10 | c.2400G>T p.V800= | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as COSV100995052; called by muse, mutect2
- OR10J1 | c.336C>T p.C112= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as rs375983493; called by mutect2, varscan2
- OR1A1 | c.114A>G p.T38= | Silent (SNP) | VAF 138/521 reads (26%) | catalogued as rs773114544, COSV100410835; called by muse, mutect2, varscan2
- PRB1 | c.303C>T p.P101= | Silent (SNP) | VAF 202/654 reads (31%) | catalogued as rs1461398983, COSV99556059; called by muse, varscan2
- PTPRD | c.1464T>C p.Y488= | Silent (SNP) | VAF 110/304 reads (36%) | catalogued as rs1254386290, COSV100647105; called by muse, varscan2
- RBM39 | c.367C>A p.R123= | Silent (SNP) | VAF 28/374 reads (7%) | catalogued as COSV53617306, COSV99488921; called by muse, mutect2
- SLIT2 | c.3147C>T p.H1049= | Silent (SNP) | VAF 425/590 reads (72%) | catalogued as rs756872945, COSV56582524, COSV56598699; called by muse, mutect2, varscan2
- SVIL | c.1518C>T p.P506= | Silent (SNP) | VAF 161/306 reads (53%) | catalogued as COSV100881550; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846397 G>T | 5'Flank (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- DMAC2 | c.*868_*885del | 3'UTR (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- TFE3 | c.*434C>A | 3'UTR (SNP) | VAF 13/244 reads (5%) | catalogued as COSV100252842; called by muse, mutect2
